Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UV-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of cervix":

Squamous cell carcinoma, invasive and ulcerated.
Angiolymphatic invasion absent.

ICD-O-3
Carcinoma, squamous NOS
8070/3
Site: Cervix NOS
C53.9
J23/7/14

Source: NCI Genomic Data Commons file d68dfdbc-ddcb-42f1-97ff-46d14f574a82 (TCGA-VS-A9UV.EAF200A1-9A0C-4A51-A241-14173B4F323E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).